Surgical pathology report (de-identified scan), TCGA case TCGA-86-8054, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-8054-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

[Redacted]

[Redacted] ID	OpenClinica ID	Gross Description	Microscopic Description	Diagnosis Details	Comments
[Redacted]	[Redacted]				

[page 2 of 2]
Formatted Path Report	Laterality/Location		Date of excision
LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 6 x 6 x 7 cm Histologic type: Acinar cell adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 3/13 positive for metastasis (Hilar 3/13) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	Right- upper		

Source: NCI Genomic Data Commons file 0d29e354-09d7-4ec9-a9a0-538c822717a5 (TCGA-86-8054.A47B8835-2314-4631-B55D-F99AF91AD5E7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).